Gene-level copy-number profile of tumor specimen ALCH-B4KI-TTP1-A from ALCHEMIST case ALCH-B4KI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,133 days).
Specimen ALCH-B4KI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6affd36-9109-4be6-9538-17ebc3735489.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4KI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,258 have no estimate.
https://portal.gdc.cancer.gov/files/3248773e-dcf7-4909-9b86-f13f98dfd242

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 7,601; copy number 2: 50,582; copy number 3: 81; copy number 4: 31; copy number 5: 2; copy number 6: 8; copy number 7: 4; copy number 9: 2; copy number 10: 1; copy number 11: 32; copy number 12: 4; copy number 13: 1; copy number 27: 5.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:125,703,349–125,735,198, 4 genes: OR7E130P, OR7E29P, OR7E93P, OR7E53P.
- chr8:139,508,701–139,508,971, 1 gene: AC090093.1.
- chr10:48,443,836–48,445,820, 1 gene: AC016397.2.
- chr12:31,076,867–31,077,016, 1 gene (within-gene range 0–1): SNORA75.
- chr14:105,597,691–105,601,728, 1 gene: IGHE.
- chr17:32,970,376–32,997,877, 1 gene: SPACA3.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 59 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,965,025–144,965,135, 1 gene, copy number 5: AC242498.1.
- chr5:70,049,638–70,078,522, 2 genes, copy number 9: SMN2, AC140134.1.
- chr8:7,836,436–8,008,755, 7 genes, copy number 6–12 (within-gene range 3–12): DEFB104A, SPAG11A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E.
- chr8:7,990,415–8,024,652, 3 genes, copy number 12: DEFB109C, FAM90A11P, FAM90A24P.
- chr11:129,279–186,136, 2 genes, copy number 7 (within-gene range 2–7): AC069287.3, RNU6-447P.
- chr15:21,328,380–21,946,641, 35 genes, copy number 11–27: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr16:32,250,620–32,255,922, 2 genes, copy number 6: AC133485.3, TP53TG3D.
- chr21:13,095,305–13,113,790, 1 gene, copy number 5: ZNF355P.
- chr21:43,092,956–43,172,805, 6 genes, copy number 6–13: U2AF1, AP001631.2, MRPL51P2, FRGCA, AP001631.1, CRYAA.

Autosomal genes at a single copy (total copy number 1): 7,598. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
